Somatic mutation profile of tumor specimen BA2410D (aliquot aq-BA2410D) from BEATAML1.0 case 2495, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,902 days).
Specimen BA2410D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1939fec8-38eb-4283-9264-93cda4b8a36f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2966D (Solid Tissue Normal), aliquot aq-BA2966D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/060e5406-15a4-4abe-b419-aabdbe98fbf8

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Del 3, Silent 2, Frame Shift Ins 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 20/76 reads (26%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- IRGC | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.441); catalogued as rs762085853, COSV54983792; called by muse, mutect2, varscan2
- MAN2A2 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs752873849; called by muse, mutect2, varscan2
- CPXM1 | c.583G>T p.V195F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.129); called by muse, mutect2
- DNMT3A | c.870_876del p.F290Lfs*24 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | called by mutect2, pindel, varscan2
- DTX3 | c.590A>G p.K197R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.17); called by muse, mutect2
- DUSP3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); called by muse, mutect2
- EPHX3 | c.522G>C p.W174C | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM135A | c.2650G>A p.D884N (on ENST00000370479 / NM_001351599.1; = p.D671N on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRP14 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- TET3 | c.1278del p.A427Qfs*114 | Frame Shift Del (DEL) | VAF 97/256 reads (38%) | called by mutect2, pindel, varscan2
- TOR2A | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.386); called by muse, mutect2
- ZNF764 | c.1032del p.C345Afs*38 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- LPAR5 | c.489G>T p.S163= | Silent (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- TANC1 | c.1230G>A p.A410= | Silent (SNP) | VAF 89/304 reads (29%) | catalogued as rs371911240; called by muse, mutect2, varscan2
- IL10RA | c.*170C>A | 3'UTR (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
